Somatic mutation profile of tumor specimen MP2PRT-PAUMWV-TMP1-A (aliquot MP2PRT-PAUMWV-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUMWV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (738 days).
Specimen MP2PRT-PAUMWV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bdfa6d8-fc38-4f47-a51e-96591cd19f86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMWV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMWV-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/940d7104-0a0c-40a0-882c-422320a44ec0

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 132/434 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRD2 | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 139/298 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1464681818, COSV100601368; called by muse, mutect2, varscan2
- CLDN14 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 152/1053 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs747254086, COSV59777692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARK1 | c.546T>A p.D182E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV65065943; called by muse, mutect2, varscan2
- OTUD4 | c.3046G>A p.V1016M (on ENST00000447906 / NM_001366057.1; = p.V951M on NM_001102653.1) | Missense Mutation (SNP) | VAF 88/314 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs1163935496; called by muse, mutect2, varscan2
- RNASE11 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 106/464 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV100250512; called by muse, mutect2, varscan2
- RPS29 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 95/509 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs769742652, COSV55421061; called by muse, mutect2, varscan2
- SHF | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.056); catalogued as rs374215190, COSV99334718; called by muse, mutect2, varscan2
- STK24 | c.992dup p.S332Qfs*2 | Frame Shift Ins (INS) | VAF 102/279 reads (37%) | catalogued as rs758627015; called by mutect2, pindel, varscan2
- CAPN1 | c.902T>A p.V301E | Missense Mutation (SNP) | VAF 95/274 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CFAP100 | c.419-1G>C p.X140_splice | Splice Site (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- GTPBP1 | c.278C>A p.T93N | Missense Mutation (SNP) | VAF 28/529 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2
- KRTAP10-11 | c.45C>A p.D15E | Missense Mutation (SNP) | VAF 80/734 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.112); called by muse, varscan2
- MIA2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 230/349 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TAS2R20 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 25/558 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2
- PERM1 | c.1995C>T p.F665= | Silent (SNP) | VAF 130/558 reads (23%) | catalogued as rs950072658; called by muse, mutect2, varscan2
- QTRT1 | c.819T>C p.L273= | Silent (SNP) | VAF 77/319 reads (24%) | catalogued as rs778591627; called by muse, mutect2, varscan2
- SSU72P8 | c.405C>T p.H135= | Silent (SNP) | VAF 90/454 reads (20%) | catalogued as rs782481967; called by muse, mutect2, varscan2
- TDRD6 | c.1941C>T p.D647= | Silent (SNP) | VAF 60/379 reads (16%) | catalogued as rs757247390, COSV60177394; called by muse, mutect2, varscan2
